Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A3ES, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A3ES-06A (Metastatic).

FINAL DIAGNOSIS:
PERITONEAL TUMORS, EXCISION -
MULTIPLE RECURRENT METASTATIC MALIGNANT MELANOMA.

Collection Date:

PATIENT HISTORY:

The patient has a clinical history of melanoma.
PRE-OP DIAGNOSIS: Recurrent intra-abdominal malignant melanoma.
POST-OP DIAGNOSIS: Same.

ICD-0-3

Melanoma, NOS 8720/3

Site: peritoneum, NOS C48.2

11/4/11

Source: NCI Genomic Data Commons file 48da7c6e-6496-44b5-8804-09590c20b8ef (TCGA-ER-A3ES.096BC4D5-2921-447D-BCF1-18CE550249A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).